CPTAC case C3L-03262 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e9473087-ea4f-4197-ae8a-cd3f59c38aaa

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 68.3 years (24,929 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 97 days; Days to last follow up: 97 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 12; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 97 days; Disease response: Tumor Free.

Other clinical attributes
- Weight: 68.6 kg; Height: 160 cm; BMI: 26.8.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03262-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 130 mg; Time between clamping and freezing: 78 minutes; Time between excision and freezing: 35 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03262-21: Section location: Right Upper Lobe; Percent tumor nuclei: 65; Percent necrosis: 5.
- Sample C3L-03262-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 120 mg; Time between clamping and freezing: 78 minutes; Time between excision and freezing: 35 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03262-23: Section location: Right Upper Lobe; Percent tumor nuclei: 60; Percent necrosis: 5.
- Sample C3L-03262-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 60 mg; Time between clamping and freezing: 82 minutes; Time between excision and freezing: 39 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03262-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 70 mg; Time between clamping and freezing: 82 minutes; Time between excision and freezing: 39 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03262-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
